FM case AD4911 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/2341f2e7-f02e-4de7-bf26-8a875392ca04

Male, 80.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the head, face or neck; specimen biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
